Somatic mutation profile of tumor specimen TCGA-BP-4760-01A (aliquot TCGA-BP-4760-01A-02D-1421-08) from TCGA case TCGA-BP-4760, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 69.2 years (25,268 days).
Specimen TCGA-BP-4760-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed654ec3-fb9e-41bc-b46d-f10958276468.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4760-11A (Solid Tissue Normal), aliquot TCGA-BP-4760-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24da9b29-ccb2-46bc-b173-4a8d714f8282

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 8, Silent 5, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBLL1 | c.1271A>T p.Y424F | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV56027781; called by muse, mutect2
- CFAP65 | c.2171G>T p.C724F | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.408); catalogued as COSV58557411, COSV58561710; called by muse, mutect2
- DSP | c.1693A>G p.I565V | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1287232143, COSV65790747; called by muse, mutect2, varscan2
- LRP4 | c.162C>A p.D54E | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.103); catalogued as COSV66133726; called by muse, mutect2, varscan2
- NPRL3 | c.1268C>T p.P423L (on ENST00000611875 / NM_001077350.3; = p.P398L on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs200792895; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- NUDT12 | c.628C>T p.L210F | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV50090288; called by muse, mutect2
- PACSIN3 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 104/370 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV54065007; called by muse, mutect2, varscan2
- MAGEB6B | c.699C>G p.F233L | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.035); called by muse, mutect2
- TFG | c.83del p.N28Mfs*9 | Frame Shift Del (DEL) | VAF 61/235 reads (26%) | called by mutect2, pindel, varscan2
- ARHGAP35 | c.2712G>A p.Q904= | Silent (SNP) | VAF 53/188 reads (28%) | catalogued as COSV68328927; called by muse, mutect2, varscan2
- CD9 | c.108A>G p.R36= | Silent (SNP) | VAF 12/196 reads (6%) | catalogued as COSV50529875; called by muse, mutect2
- PEG3 | c.2808T>C p.R936= | Silent (SNP) | VAF 72/328 reads (22%) | catalogued as COSV55623336; called by muse, mutect2, varscan2
- SLC36A1 | c.78G>A p.S26= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as rs142064945; called by muse, mutect2, varscan2
- TLR4 | c.945G>C p.L315= (on ENST00000355622 / NM_138554.5; = p.L275= on NM_003266.4) | Silent (SNP) | VAF 59/230 reads (26%) | catalogued as COSV62922294; called by muse, mutect2, varscan2
